Somatic mutation profile of tumor specimen TCGA-44-8119-01A (aliquot TCGA-44-8119-01A-11D-2238-08) from TCGA case TCGA-44-8119, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.9 years (27,003 days).
Specimen TCGA-44-8119-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de3d8411-e578-4519-8785-2d0794a1dcad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-8119-10A (Blood Derived Normal), aliquot TCGA-44-8119-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbb774df-457d-4346-83fd-c4222929906e

The open-access MAF lists 688 somatic variants for this specimen: 530 protein-altering or splice-affecting, 143 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 464, Silent 143, Nonsense Mutation 32, Frame Shift Del 14, RNA 8, Frame Shift Ins 7, Splice Site 6, Splice Region 6, Intron 3, 3'UTR 2, 3'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs281875227, CM122492, COSV100759471, COSV60785471; ClinVar: pathogenic; called by muse, mutect2
- A4GNT | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1022472732, COSV52628526; called by muse, mutect2, varscan2
- ABCA7 | c.1105C>A p.H369N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV54025031; called by muse, mutect2
- ACKR1 | c.496A>T p.T166S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.799); catalogued as COSV63671945; called by muse, mutect2, varscan2
- ACKR3 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.294); catalogued as COSV56020725; called by muse, mutect2, varscan2
- ACOXL | c.76-1G>T p.X26_splice | Splice Site (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100489870; called by muse, mutect2, varscan2
- ACOXL | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV100489873, COSV61330294; called by muse, mutect2, varscan2
- ACRV1 | c.685C>G p.Q229E | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV59754618; called by muse, mutect2
- ACTN2 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63972650; called by muse, mutect2, varscan2
- ACVR1C | c.326T>A p.L109H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.765); catalogued as COSV99694316, COSV99694363; called by muse, mutect2, varscan2
- ACVR1C | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.013); catalogued as COSV54647492; called by muse, mutect2, varscan2
- ACVRL1 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023316, CM050024, CM147634, COSV66359684; called by muse, mutect2, varscan2
- ADAM19 | c.1263C>A p.N421K | Missense Mutation (SNP) | VAF 102/210 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV57423449, COSV57423940; called by muse, mutect2, varscan2
- ADAP2 | c.823A>T p.K275* | Nonsense Mutation (SNP) | VAF 43/278 reads (15%) | catalogued as COSV58295202; called by muse, mutect2, varscan2
- ADD3 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53320897; called by muse, mutect2, varscan2
- ADGRB3 | c.4217C>T p.T1406M | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs368886155; called by muse, mutect2, varscan2
- ADGRF4 | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 102/144 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as rs369486491, COSV51950127; called by muse, mutect2, varscan2
- ADH6 | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52955267; called by muse, mutect2, varscan2
- AFAP1L1 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57044102; called by muse, mutect2, varscan2
- AFAP1L2 | c.483C>A p.Y161* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV58412710; called by muse, mutect2, varscan2
- AFDN | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV60038918; called by muse, mutect2, varscan2
- AGL | c.4162-1G>T p.X1388_splice | Splice Site (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99648419; called by muse, mutect2
- AGMO | c.994T>A p.S332T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV61107089; called by muse, mutect2, varscan2
- AHNAK | c.10544C>T p.P3515L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57205624; called by muse, mutect2, varscan2
- AICDA | c.240G>T p.W80C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as COSV57563608; called by muse, mutect2, varscan2
- ANK2 | c.4700G>T p.R1567I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52148928; called by muse, mutect2, varscan2
- ANK2 | c.5473C>A p.P1825T | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV52148942; called by muse, mutect2, varscan2
- ANK2 | c.6657G>T p.M2219I | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.121); catalogued as COSV52148953; called by muse, mutect2, varscan2
- ARAF | c.860A>T p.D287V | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV51691486; called by muse, mutect2, varscan2
- ARHGAP20 | c.1825C>T p.Q609* | Nonsense Mutation (SNP) | VAF 15/181 reads (8%) | catalogued as COSV52807408; called by muse, mutect2
- ARMC3 | c.384T>A p.F128L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV53058002; called by muse, mutect2
- ARMC8 | c.400A>T p.T134S (on ENST00000469044 / NM_001363941.2; = p.T120S on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.043); catalogued as COSV61767764; called by muse, mutect2, varscan2
- ARMCX5 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 35/45 reads (78%) | catalogued as COSV55766047, COSV99863476; called by muse, mutect2, varscan2
- ARSG | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV71592636; called by muse, mutect2, varscan2
- ASB10 | c.721C>A p.P241T (on ENST00000420175 / NM_001142459.2; = p.P226T on NM_080871.4) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.884); catalogued as COSV51994660; called by muse, mutect2, varscan2
- ASB12 | c.200G>T p.R67M | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV62856189; called by muse, mutect2, varscan2
- ASB3 | c.265C>A p.Q89K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV55074123; called by muse, mutect2, varscan2
- ASIC5 | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72232541, COSV72233031; called by muse, mutect2, varscan2
- ASPHD1 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV58097609; called by muse, mutect2
- ASPM | c.7595A>T p.H2532L | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV54125811; called by muse, mutect2
- ASTN2 | c.1088C>A p.T363K | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs201644531, COSV57755872; called by muse, mutect2, varscan2
- ASXL2 | c.2180C>T p.P727L | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV55454631; called by muse, mutect2, varscan2
- ATG9A | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs1276938510, COSV60132360; called by muse, mutect2, varscan2
- ATP2A2 | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV57875097; called by muse, mutect2, varscan2
- ATXN3 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV61493917; called by muse, mutect2, varscan2
- B3GNT5 | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58475508; called by muse, mutect2, varscan2
- B3GNT6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV62827947; called by muse, mutect2, varscan2
- BBS7 | c.1545C>G p.F515L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52654934; called by muse, mutect2, varscan2
- BCL11A | c.632G>T p.G211V (on ENST00000335712 / NM_001365609.1; = p.G245V on NM_018014.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV100184727; called by muse, mutect2, varscan2
- BCL9L | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.034); catalogued as COSV100599512; called by mutect2, varscan2
- BCR | c.2772G>T p.K924N | Missense Mutation (SNP) | VAF 136/183 reads (74%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV59927986; called by muse, mutect2, varscan2
- BICC1 | c.1282C>A p.P428T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV54062285, COSV54067794; called by muse, mutect2, varscan2
- BIN1 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs755355125, COSV52116301; called by muse, mutect2, varscan2
- BMP1 | c.286A>T p.S96C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV59244098; called by muse, mutect2, varscan2
- BMP7 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476787716, COSV67779744, COSV67781505; called by muse, mutect2, varscan2
- BOC | c.2420G>A p.C807Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56347703, COSV56359507; called by muse, mutect2, varscan2
- BPIFB1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs201145500; called by muse, mutect2, varscan2
- BPIFC | c.597C>A p.L199= | Splice Region (SNP) | VAF 19/26 reads (73%) | catalogued as COSV55910803, COSV55911158; called by muse, mutect2, varscan2
- BRCA1 | c.4581G>T p.E1527D | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV58785312; called by muse, mutect2, varscan2
- BRINP2 | c.709T>A p.Y237N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64175960; called by muse, mutect2, varscan2
- BRWD3 | c.3151G>T p.G1051C | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as COSV64744568; called by muse, mutect2
- BRWD3 | c.3149T>A p.I1050N | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV64744579; called by muse, mutect2
- BSN | c.4547A>G p.D1516G | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as COSV56513863; called by muse, mutect2, varscan2
- C4BPA | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV65535824, COSV65537022; called by muse, mutect2, varscan2
- C6 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs762327241, COSV54705765, COSV54706317; called by muse, mutect2, varscan2
- C7 | c.439C>A p.L147I | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated (0.26); PolyPhen benign (0.255); catalogued as COSV57471665; called by muse, mutect2, varscan2
- CACNA1A | c.4574T>G p.M1525R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64191540; called by muse, mutect2, varscan2
- CARD6 | c.1619G>C p.W540S | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV54564550; called by muse, mutect2, varscan2
- CASK | c.2385A>C p.Q795H (on ENST00000378163 / NM_001367721.1; = p.Q790H on NM_003688.3) | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV59362724; called by muse, mutect2
- CATSPERG | c.2855G>T p.G952V | Missense Mutation (SNP) | VAF 369/901 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53046671; called by muse, mutect2, varscan2
- CBY2 | c.683T>G p.V228G | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV60117381; called by muse, mutect2, varscan2
- CD109 | c.895A>C p.M299L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54646127; called by muse, mutect2, varscan2
- CD163L1 | c.2791C>A p.P931T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.215); catalogued as COSV58012088; called by muse, mutect2, varscan2
- CD1A | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV56860577, COSV56861479; called by muse, mutect2, varscan2
- CD1A | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs371364380; called by muse, mutect2, varscan2
- CDH13 | c.931G>T p.V311F | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51796630; called by muse, mutect2, varscan2
- CDH23 | c.4996C>A p.P1666T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.598); catalogued as COSV56450949; called by muse, mutect2, varscan2
- CDKAL1 | c.1049A>G p.K350R | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV51180427; called by muse, mutect2, varscan2
- CEACAM4 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 31/153 reads (20%) | catalogued as COSV55730816; called by muse, mutect2, varscan2
- CEP57L1 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV61244291; called by muse, mutect2, varscan2
- CFAP91 | c.689G>C p.G230A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56339569; called by muse, mutect2, varscan2
- CFHR3 | c.402G>T p.W134C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66401618; called by muse, mutect2, varscan2
- CHD3 | c.2140C>G p.P714A | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57873028; called by muse, mutect2, varscan2
- CHD9 | c.3001A>G p.R1001G | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54608224; called by muse, mutect2, varscan2
- CKAP2L | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56695829; called by muse, mutect2, varscan2
- CLCA1 | c.1688C>A p.T563N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.74); catalogued as COSV52325616; called by muse, mutect2, varscan2
- CLEC12B | c.190T>C p.F64L | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.303); catalogued as COSV58862665; called by muse, mutect2, varscan2
- CLEC4D | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.336); catalogued as rs765594498, COSV55228247; called by muse, mutect2, varscan2
- CNTNAP5 | c.3160C>G p.L1054V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV101443140, COSV70475536; called by muse, mutect2, varscan2
- COL16A1 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV54701606; called by muse, mutect2, varscan2
- COL19A1 | c.901G>C p.G301R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV59567036; called by muse, mutect2, varscan2
- COL4A5 | c.1834G>T p.G612C | Missense Mutation (SNP) | VAF 64/77 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60357080; called by muse, mutect2, varscan2
- COL7A1 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.197); catalogued as COSV60392066; called by muse, mutect2, varscan2
- CPSF1 | c.2029G>A p.G677S | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV58232428; called by muse, mutect2, varscan2
- CPXCR1 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as rs999680883, COSV52161247; called by muse, mutect2, varscan2
- CR2 | c.2427T>A p.N809K | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV65506298; called by muse, mutect2, varscan2
- CRADD | c.243G>T p.W81C | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60552323; called by muse, mutect2, varscan2
- CRB2 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63502005; called by muse, mutect2, varscan2
- CREB3L2 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV100381624, COSV57792666; called by muse, mutect2, varscan2
- CSMD1 | c.7208C>T p.T2403I (on ENST00000520002; = p.T2402I on NM_033225.6) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs981286020, COSV59289834; called by muse, mutect2
- CSMD2 | c.7763G>T p.C2588F | Missense Mutation (SNP) | VAF 100/195 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53885856; called by muse, mutect2, varscan2
- CSMD3 | c.9931T>C p.S3311P (on ENST00000297405 / NM_001363185.1; = p.S3142P on NM_052900.3) | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52116361; called by muse, mutect2, varscan2
- CUBN | c.791G>T p.R264I | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV64709196; called by muse, mutect2, varscan2
- DCAF1 | c.4336G>A p.A1446T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs372451907, COSV60041116; called by muse, mutect2, varscan2
- DCLK3 | c.498G>T p.M166I | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101373862; called by muse, mutect2, varscan2
- DCLK3 | c.497T>A p.M166K | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV101373864; called by muse, mutect2, varscan2
- DDB1 | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.257); catalogued as COSV57101136, COSV57101337; called by muse, mutect2, varscan2
- DDO | c.232A>T p.I78F | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.958); catalogued as COSV64469770; called by muse, mutect2, varscan2
- DDR2 | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63369684; called by muse, mutect2, varscan2
- DGKB | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV51761564, COSV51781556; called by muse, mutect2, varscan2
- DISP3 | c.2150T>A p.L717Q | Missense Mutation (SNP) | VAF 59/89 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53821826; called by muse, mutect2, varscan2
- DLG5 | c.1881G>T p.T627= | Splice Region (SNP) | VAF 20/74 reads (27%) | catalogued as COSV64947039, COSV64947452; called by muse, mutect2, varscan2
- DNAH7 | c.2385A>T p.Q795H | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV56754346; called by muse, mutect2, varscan2
- DNAH9 | c.8449C>A p.P2817T | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52337677; called by muse, mutect2, varscan2
- DOK6 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66927035; called by muse, mutect2, varscan2
- DPPA2 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.293); catalogued as COSV72117941; called by muse, mutect2, varscan2
- DRD2 | c.1088T>A p.L363H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.926); catalogued as COSV100669284; called by muse, mutect2
- DRP2 | c.1743G>T p.W581C | Missense Mutation (SNP) | VAF 134/164 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65809432, COSV65811836; called by muse, mutect2, varscan2
- DST | c.17014G>T p.E5672* (on ENST00000361203 / NM_001374722.1; = p.E3369* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 43/136 reads (32%) | catalogued as COSV55000869; called by muse, mutect2, varscan2
- DTX4 | c.1673C>A p.A558D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99914971; called by muse, mutect2, varscan2
- DYNC1H1 | c.3796C>G p.P1266A | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64134815; called by muse, mutect2, varscan2
- DZIP3 | c.2536A>G p.K846E | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.746); catalogued as COSV64311282; called by muse, mutect2, varscan2
- ECEL1 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.119); catalogued as COSV58811462; called by muse, mutect2, varscan2
- EFCAB11 | c.83A>T p.K28I | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV50860682; called by muse, mutect2, varscan2
- EIF5AL1 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73122929; called by muse, mutect2, varscan2
- ENAM | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV68535378; called by muse, mutect2, varscan2
- ENOX1 | c.360T>A p.C120* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as COSV54889440, COSV54908296; called by muse, mutect2, varscan2
- EPB41L2 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751876828, COSV61353690; called by muse, mutect2, varscan2
- EPHB6 | c.713del p.R238Hfs*37 | Frame Shift Del (DEL) | VAF 52/167 reads (31%) | catalogued as COSV67420408; called by mutect2, pindel, varscan2
- EPHB6 | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146734346; called by muse, mutect2, varscan2
- ESR1 | c.1369G>T p.G457* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV52783546; called by muse, mutect2, varscan2
- ESX1 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV65423987; called by muse, mutect2, varscan2
- F11 | c.408C>G p.C136W | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM044882, COSV53004539; called by muse, mutect2, varscan2
- F5 | c.5609A>G p.K1870R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.046); catalogued as rs1373062248, COSV63121375; called by muse, mutect2, varscan2
- FAM171B | c.1374C>A p.D458E | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.855); catalogued as COSV59001203; called by muse, mutect2, varscan2
- FAM172A | c.1074G>T p.E358D | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV67934345; called by muse, mutect2, varscan2
- FAM177B | c.339G>A p.K113= | Splice Region (SNP) | VAF 17/41 reads (41%) | catalogued as rs1483622669, COSV62600940; called by muse, mutect2, varscan2
- FAP | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); catalogued as COSV51859148; called by muse, mutect2, varscan2
- FAT3 | c.5336G>T p.S1779I | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99961677; called by muse, mutect2, varscan2
- FAT4 | c.10072T>C p.Y3358H | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs984954785, COSV58674041; called by muse, mutect2, varscan2
- FCGBP | c.8128G>A p.V2710M | Missense Mutation (SNP) | VAF 30/674 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.278); catalogued as rs777962625; called by muse, mutect2
- FCGR1A | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.341); catalogued as COSV64985225; called by muse, mutect2
- FEZ1 | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV54026736, COSV54027048; called by muse, mutect2, varscan2
- FGA | c.1391C>A p.T464N | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100119985; called by muse, mutect2, varscan2
- FLG2 | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.452); catalogued as COSV66167028; called by muse, mutect2, varscan2
- FLT1 | c.2026_2027insTGCT p.S676Mfs*11 | Frame Shift Ins (INS) | VAF 14/82 reads (17%) | catalogued as COSV99147560; called by mutect2, pindel, varscan2
- FREM1 | c.5674C>G p.L1892V | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.387); catalogued as rs750826286, COSV66518771; called by muse, mutect2, varscan2
- FRY | c.4206A>T p.R1402S | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV66566209; called by muse, mutect2, varscan2
- FZD2 | c.1561T>A p.Y521N | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59528224; called by muse, mutect2, varscan2
- GABBR1 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV63541204; called by muse, mutect2, varscan2
- GABRA4 | c.1643A>T p.E548V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.695); catalogued as COSV51923479, COSV99973778; called by muse, mutect2, varscan2
- GABRG1 | c.1037C>A p.A346E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1207133292, COSV54950691, COSV54952481; called by mutect2, varscan2
- GALNT5 | c.1496G>C p.S499T | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.55); catalogued as COSV52036137, COSV52036265; called by muse, mutect2, varscan2
- GALNT6 | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.013); catalogued as COSV62541767; called by muse, mutect2
- GATA2 | c.1204A>C p.N402H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV62003338; called by muse, mutect2, varscan2
- GBP5 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.067); catalogued as rs750275362, COSV58591800; called by muse, mutect2, varscan2
- GCN1 | c.5687C>T p.T1896I | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV56104614; called by muse, mutect2, varscan2
- GFRA3 | c.982T>A p.C328S | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV51228017; called by muse, mutect2, varscan2
- GKAP1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.797); catalogued as COSV64488675; called by muse, mutect2, varscan2
- GLRA1 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51008131; called by muse, mutect2, varscan2
- GOLGA5 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs941014977, COSV50832177; called by muse, mutect2, varscan2
- GPIHBP1 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 113/168 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV58209039; called by muse, mutect2, varscan2
- GPNMB | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs776093177, COSV51697161; called by muse, mutect2, varscan2
- GREB1 | c.3334G>T p.E1112* | Nonsense Mutation (SNP) | VAF 132/301 reads (44%) | catalogued as COSV52182053, COSV52187241; called by muse, mutect2, varscan2
- GRID1 | c.1228C>G p.R410G | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100022404, COSV60016469, COSV60056647; called by muse, mutect2, varscan2
- GRM1 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51112187; called by muse, mutect2, varscan2
- GRM1 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51112256; called by muse, mutect2, varscan2
- GRSF1 | c.563G>T p.R188I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV99635499; called by muse, mutect2, varscan2
- GRSF1 | c.562A>T p.R188* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as COSV99635508; called by muse, mutect2, varscan2
- GTPBP4 | c.1136A>T p.E379V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV62550273; called by muse, mutect2, varscan2
- HACE1 | c.1691G>C p.R564T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV53499735; called by muse, mutect2, varscan2
- HBD | c.114G>T p.W38C | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53082068; called by muse, mutect2, varscan2
- HCRTR2 | c.863C>A p.A288D | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.449); catalogued as COSV63794173; called by muse, mutect2, varscan2
- HECW2 | c.333G>T p.R111S | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53651429; called by muse, mutect2, varscan2
- HEPH | c.1977G>T p.M659I (on ENST00000343002; = p.M392I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57960075; called by muse, mutect2, varscan2
- HGFAC | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV101237725; called by muse, mutect2, varscan2
- HOXC8 | c.581A>T p.K194M | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50000536; called by muse, mutect2
- HPGD | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs187367875, COSV56661776; called by muse, mutect2, varscan2
- HPS1 | c.856T>A p.S286T | Missense Mutation (SNP) | VAF 91/248 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV57266736; called by muse, mutect2, varscan2
- HS1BP3 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV58312127; called by muse, mutect2, varscan2
- HS2ST1 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1390292605, COSV63348945; called by muse, mutect2, varscan2
- HS3ST3A1 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99404029; called by muse, mutect2, varscan2
- HTRA4 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750960313, COSV56758553; called by muse, mutect2, varscan2
- HYDIN | c.5751G>A p.M1917I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.173); catalogued as COSV99991897; called by muse, mutect2, varscan2
- HYDIN | c.2014G>C p.A672P | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55478939; called by muse, mutect2, varscan2
- ICE1 | c.5915A>G p.H1972R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV56820224; called by muse, mutect2, varscan2
- IGFBP2 | c.723G>C p.M241I | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV52079589; called by muse, mutect2, varscan2
- IGHV2-70 | c.298G>T p.V100F | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT tolerated (0.73); PolyPhen benign (0.013); catalogued as rs372665325; called by muse, mutect2, varscan2
- IGKV2D-29 | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV101534356; called by muse, mutect2, varscan2
- IGSF9B | c.3010G>T p.E1004* | Nonsense Mutation (SNP) | VAF 32/75 reads (43%) | catalogued as rs371141922, COSV58064547; called by muse, mutect2, varscan2
- IL1RL1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as rs772536038, COSV52112814; called by muse, mutect2, varscan2
- INTS4 | c.1500G>T p.R500S | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101417124; called by muse, mutect2, varscan2
- INTS4 | c.1499G>T p.R500M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101417125; called by muse, mutect2, varscan2
- INTS5 | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.858); catalogued as rs1306720587, COSV57950494; called by muse, mutect2, varscan2
- IQCC | c.526T>C p.W176R | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163380655, COSV52207817; called by muse, mutect2, varscan2
- IQSEC3 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV100406796; called by muse, mutect2, varscan2
- IQSEC3 | c.2143G>C p.D715H (on ENST00000538872 / NM_001170738.2; = p.D412H on NM_015232.1) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV58281399; called by muse, mutect2, varscan2
- IRF2BPL | c.2230A>G p.R744G | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53146233; called by muse, mutect2, varscan2
- ISM2 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs749516021, COSV53634134; called by muse, mutect2, varscan2
- ITFG1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57744755; called by muse, mutect2, varscan2
- ITGAM | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV54934571; called by muse, mutect2, varscan2
- ITGAX | c.2096G>T p.S699I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV51642343; called by muse, mutect2, varscan2
- ITIH5 | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV56899036; called by muse, mutect2, varscan2
- ITPR3 | c.7170C>A p.F2390L | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65290888; called by muse, mutect2, varscan2
- ITPRID1 | c.2989G>T p.G997C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1180104593, COSV60070934; called by muse, mutect2, varscan2
- KALRN | c.7688T>A p.V2563D (on ENST00000360013 / NM_001024660.4; = p.V866D on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs1241898725, COSV52251137; called by muse, mutect2, varscan2
- KCNB2 | c.2339C>A p.P780H | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV73049170; called by muse, mutect2, varscan2
- KCNJ4 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211791138, COSV57856309; called by muse, mutect2, varscan2
- KCNK6 | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54579040; called by muse, mutect2, varscan2
- KCNS2 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54637528; called by muse, mutect2, varscan2
- KCNT2 | c.3359G>C p.S1120T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV54067123; called by muse, mutect2, varscan2
- KCNV2 | c.1348T>A p.W450R | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748180390, CM074303, CM1110040, COSV66055601; called by muse, mutect2, varscan2
- KDM4C | c.300G>T p.R100S | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV67184135; called by muse, mutect2, varscan2
- KERA | c.299T>A p.I100K | Missense Mutation (SNP) | VAF 58/92 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99899294; called by muse, varscan2
- KHDRBS2 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55431788; called by muse, mutect2, varscan2
- KHDRBS2 | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); catalogued as COSV55431799; called by muse, mutect2, varscan2
- KIAA0319L | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.147); catalogued as COSV57842765; called by muse, mutect2, varscan2
- KIAA1549L | c.4901T>G p.V1634G (on ENST00000321505; = p.V1931G on NM_012194.3) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.997); catalogued as COSV58583065; called by muse, mutect2
- KIF4B | c.1412A>T p.Q471L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV70528164, COSV70529230; called by muse, mutect2, varscan2
- KITLG | c.605-2A>G p.X202_splice | Splice Site (SNP) | VAF 14/32 reads (44%) | catalogued as COSV57200257; called by muse, mutect2, varscan2
- KLHL1 | c.1424C>A p.T475N | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV64767904; called by muse, mutect2, varscan2
- KRT17 | c.770G>C p.R257P | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60860104, COSV60860584; called by muse, mutect2, varscan2
- KRT25 | c.1030C>A p.Q344K | Missense Mutation (SNP) | VAF 99/336 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV56443881; called by muse, mutect2, varscan2
- KRT3 | c.1415A>T p.Q472L | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV58814827; called by muse, mutect2, varscan2
- KRT34 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.547); catalogued as COSV67449352; called by muse, mutect2, varscan2
- KRT37 | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99845255; called by muse, mutect2, varscan2
- KRTAP9-3 | c.71T>G p.V24G | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.14); catalogued as COSV100893109; called by muse, mutect2, varscan2
- L1CAM | c.2501G>T p.R834L | Missense Mutation (SNP) | VAF 179/207 reads (86%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100648831, COSV62827110; called by muse, mutect2, varscan2
- L1CAM | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.714); catalogued as COSV100648841; called by muse, mutect2, varscan2
- LAMA2 | c.1743C>A p.S581R | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs774243931, COSV70340384; called by muse, mutect2, varscan2
- LAMA4 | c.3414+1G>T p.X1138_splice (on ENST00000230538 / NM_001105206.3; = p.X1131_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 12/79 reads (15%) | catalogued as COSV57892717; called by muse, mutect2, varscan2
- LAMB4 | c.1978T>C p.S660P | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV52714637; called by muse, mutect2, varscan2
- LIN37 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.029); catalogued as rs777680623, COSV50000250; called by muse, mutect2
- LMNTD2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780984275, COSV54238229; called by muse, mutect2, varscan2
- LMX1A | c.1012C>A p.L338M | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV54217692, COSV54226500; called by muse, mutect2, varscan2
- LONRF1 | c.1725G>T p.M575I | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV68036077; called by muse, mutect2, varscan2
- LRFN3 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV55817093; called by muse, mutect2, varscan2
- LRP10 | c.676C>G p.P226A | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.332); catalogued as COSV62077791; called by muse, mutect2, varscan2
- LRP1B | c.13597C>A p.L4533I | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.132); catalogued as COSV67192644; called by muse, mutect2, varscan2
- LRRIQ1 | c.646G>T p.V216F | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV67812703; called by muse, mutect2, varscan2
- LRRK2 | c.6159G>T p.Q2053H | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100109123; called by muse, mutect2, varscan2
- LRRK2 | c.6160G>T p.A2054S | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100109128, COSV54151282; called by muse, mutect2, varscan2
- LY75 | c.3700G>A p.V1234I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs765672722, COSV55102608; called by muse, mutect2, varscan2
- LZTS1 | c.1142A>G p.Q381R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV56115974; called by muse, mutect2, varscan2
- MAGEB1 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66775310; called by muse, mutect2, varscan2
- MAGEL2 | c.2125G>T p.G709C | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1401407242, COSV58566120; called by muse, mutect2, varscan2
- MCF2L2 | c.1365C>G p.C455W | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV61050133; called by muse, mutect2, varscan2
- MFAP3 | c.259A>G p.N87D | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59455488; called by muse, mutect2, varscan2
- MGST2 | c.291T>A p.Y97* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV55497374; called by muse, mutect2, varscan2
- MIOS | c.1604G>T p.R535L | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV60767261, COSV60767814; called by muse, mutect2, varscan2
- MKRN3 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58808927; called by muse, mutect2, varscan2
- MMRN1 | c.2951G>T p.C984F | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV53334423; called by muse, mutect2, varscan2
- MMUT | c.1106G>C p.R369P | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as CM990882, COSV51272456, COSV51275106, COSV51281714; called by muse, mutect2, varscan2
- MRPL1 | c.780G>T p.L260F | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV59673453; called by muse, mutect2, varscan2
- MSC | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV57696216; called by muse, mutect2
- MSH4 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54197568; called by muse, mutect2, varscan2
- MST1R | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56565435; called by muse, mutect2, varscan2
- MTMR4 | c.2308A>T p.N770Y | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.161); catalogued as COSV60199533; called by muse, mutect2, varscan2
- MTTP | c.446A>G p.K149R | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55504252; called by muse, mutect2, varscan2
- MUC16 | c.12485T>C p.L4162P | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as COSV67449759; called by muse, varscan2
- MUC5B | c.6943G>A p.E2315K | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as rs780619251, COSV71590404; called by muse, mutect2, varscan2
- MYLK3 | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1402178534, COSV67362787; called by muse, mutect2, varscan2
- NAA11 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.427); catalogued as rs757593668, COSV54514021; called by muse, mutect2
- NAV3 | c.4261C>G p.L1421V | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV57065267; called by muse, mutect2, varscan2
- NCAPD3 | c.3514G>A p.D1172N | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.632); catalogued as COSV73257938, COSV73258040; called by muse, mutect2, varscan2
- NDRG3 | c.959G>T p.S320I (on ENST00000349004 / NM_032013.4; = p.S308I on NM_022477.4) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); catalogued as COSV62421176; called by muse, mutect2, varscan2
- NDST4 | c.513C>A p.S171R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV52110903; called by muse, mutect2, varscan2
- NF1 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV62195017; called by muse, mutect2, varscan2
- NLRC4 | c.1825C>A p.L609M | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61591596; called by muse, mutect2, varscan2
- NLRP8 | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV52584148; called by muse, mutect2, varscan2
- NNT | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV52923035; called by muse, mutect2, varscan2
- NOS1 | c.1784G>T p.G595V | Missense Mutation (SNP) | VAF 67/102 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV57607948; called by muse, mutect2, varscan2
- NPAP1 | c.2343G>T p.Q781H | Missense Mutation (SNP) | VAF 107/153 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV61505049; called by muse, mutect2, varscan2
- NPHS1 | c.3005G>C p.G1002A | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV62286663, COSV62288198; called by muse, mutect2, varscan2
- NR3C1 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.185); catalogued as COSV51540403; called by muse, mutect2, varscan2
- NSG1 | c.193del p.Q65Kfs*83 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | catalogued as COSV67575695; called by mutect2, pindel, varscan2
- NT5C1A | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV52493413; called by muse, mutect2, varscan2
- NTN4 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59217739; called by muse, mutect2
- NUP210 | c.4695C>G p.I1565M | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.136); catalogued as COSV54403215; called by muse, mutect2
- NWD1 | c.3617G>T p.R1206L | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV100343964, COSV60338429; called by muse, mutect2, varscan2
- NYAP2 | c.607C>A p.L203M | Missense Mutation (SNP) | VAF 35/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55999830; called by muse, mutect2, varscan2
- OBSCN | c.1558G>T p.V520L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV52747743; called by muse, mutect2, varscan2
- OLFM2 | c.1088C>A p.T363N | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53428860; called by muse, mutect2, varscan2
- OPCML | c.869A>T p.D290V | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59408179; called by muse, mutect2, varscan2
- OR10A4 | c.944T>G p.L315R | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV101139427; called by muse, mutect2, varscan2
- OR11L1 | c.107G>T p.C36F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV63313797, COSV63316077; called by muse, mutect2
- OR2M3 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 189/437 reads (43%) | SIFT tolerated (0.95); PolyPhen benign (0.013); catalogued as COSV71758904, COSV71759246; called by muse, mutect2, varscan2
- OR2M4 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 54/144 reads (38%) | catalogued as COSV100140903; called by muse, mutect2, varscan2
- OR2T27 | c.415A>T p.K139* | Nonsense Mutation (SNP) | VAF 47/176 reads (27%) | catalogued as COSV61281011; called by muse, mutect2, varscan2
- OR4K2 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53848445; called by muse, mutect2, varscan2
- OR4N2 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 40/186 reads (22%) | catalogued as COSV60050258, COSV60051167; called by muse, varscan2
- OR51S1 | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.159); catalogued as COSV59057485; called by muse, mutect2, varscan2
- OR51T1 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 117/251 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59024031; called by muse, mutect2, varscan2
- OR52E8 | c.263T>C p.L88S | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV66205154; called by muse, mutect2, varscan2
- OR52L1 | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 86/165 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV59985975; called by muse, mutect2, varscan2
- OR56A1 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100360388; called by muse, mutect2, varscan2
- OR5AR1 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV57252964, COSV57255432; called by muse, mutect2, varscan2
- OR5AS1 | c.852G>T p.M284I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57981005; called by muse, mutect2, varscan2
- OR5T3 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV57379600; called by muse, mutect2, varscan2
- OR5W2 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV60614884; called by muse, mutect2, varscan2
- OR8J1 | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as COSV57316867, COSV57317597; called by muse, mutect2, varscan2
- OR9G4 | c.124A>T p.N42Y | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57247868; called by muse, mutect2, varscan2
- OSBPL3 | c.1730G>A p.S577N | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV57653540; called by muse, mutect2, varscan2
- OTUD6A | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57972752; called by muse, mutect2, varscan2
- PADI1 | c.23A>G p.Q8R | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64937846; called by muse, mutect2, varscan2
- PALLD | c.989T>A p.I330N | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54974550; called by muse, mutect2, varscan2
- PAPPA | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV60278489; called by muse, mutect2, varscan2
- PAX4 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV58387710; called by muse, mutect2, varscan2
- PCDH15 | c.3332C>A p.S1111Y | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57269542, COSV57272409; called by muse, mutect2, varscan2
- PCDHA6 | c.916G>C p.G306R | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV65349967; called by muse, mutect2, varscan2
- PCDHB16 | c.1815G>T p.Q605H | Missense Mutation (SNP) | VAF 100/137 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV53358678; called by muse, mutect2, varscan2
- PCDHB8 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.013); catalogued as COSV50754546; called by muse, mutect2
- PCDHB9 | c.1880C>A p.A627D | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV53376042; called by muse, mutect2, varscan2
- PCDHGA1 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100966153, COSV65295224; called by muse, mutect2, varscan2
- PCDHGA1 | c.1879C>A p.R627S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.614); catalogued as rs1390514903, COSV65295229, COSV65295848; called by muse, mutect2, varscan2
- PCDHGA3 | c.1417T>A p.S473T | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.158); catalogued as COSV53909079; called by muse, mutect2, varscan2
- PCDHGB4 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs773389466, COSV53909100; called by muse, mutect2, varscan2
- PCDHGB7 | c.1726G>C p.D576H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53909109; called by muse, mutect2, varscan2
- PCF11 | c.1633A>C p.K545Q | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV53528258; called by muse, mutect2, varscan2
- PCK1 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as COSV60126497; called by muse, mutect2, varscan2
- PCNX1 | c.1151G>T p.S384I | Missense Mutation (SNP) | VAF 70/94 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53090384; called by muse, mutect2, varscan2
- PCNX3 | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100482188; called by muse, mutect2
- PCSK4 | c.2191C>T p.L731F | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV56298469; called by muse, mutect2, varscan2
- PDGFRA | c.2762C>G p.A921G | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57265423; called by muse, mutect2, varscan2
- PEG3 | c.2228G>T p.S743I | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV55626955; called by muse, mutect2, varscan2
- PEMT | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 73/113 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.199); catalogued as rs1474440611, COSV55130120; called by muse, mutect2, varscan2
- PHF3 | c.3893A>G p.Y1298C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1392429403, COSV50314125; called by muse, mutect2, varscan2
- PHGDH | c.225G>T p.R75S | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65570445; called by muse, mutect2, varscan2
- PIGB | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs781507884, COSV51241206; called by mutect2, varscan2
- PLCB1 | c.2650G>T p.A884S | Missense Mutation (SNP) | VAF 64/104 reads (62%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV62040840; called by muse, mutect2, varscan2
- PLCB4 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53794946; called by muse, mutect2, varscan2
- PLCB4 | c.1960C>A p.P654T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV53802377; called by muse, mutect2, varscan2
- PLEKHA6 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55330745, COSV55331117; called by muse, mutect2
- PLEKHG4 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64611921; called by muse, mutect2, varscan2
- PMVK | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63785650; called by muse, mutect2, varscan2
- PNPLA7 | c.2803G>T p.A935S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99480015; called by muse, mutect2, varscan2
- POF1B | c.760C>G p.P254A | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT tolerated (0.4); PolyPhen benign (0.303); catalogued as COSV53131174; called by muse, mutect2, varscan2
- POLQ | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51747139, COSV99951994; called by muse, mutect2, varscan2
- POLRMT | c.1581G>T p.Q527H | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as COSV73933120; called by muse, mutect2, varscan2
- PPEF2 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54420618; called by muse, mutect2, varscan2
- PPHLN1 | c.1373A>T p.Q458L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as COSV56728971; called by muse, mutect2
- PRDM15 | c.3588G>T p.Q1196H | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.72); catalogued as COSV54149630; called by muse, varscan2
- PRDX3 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as rs1442689386, COSV53719279; called by muse, mutect2, varscan2
- PRF1 | c.1145C>A p.P382Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV100942515; called by muse, mutect2, varscan2
- PRKCD | c.83G>T p.C28F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57846989; called by muse, mutect2, varscan2
- PRKG1 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64784914; called by muse, mutect2, varscan2
- PRND | c.193A>T p.K65* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV59896188; called by muse, mutect2, varscan2
- PROX1 | c.2092G>T p.A698S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.323); catalogued as COSV54776479, COSV99798715; called by muse, mutect2, varscan2
- PRSS55 | c.536C>G p.T179R | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs145078199; called by muse, mutect2, varscan2
- PSG11 | c.768C>A p.N256K | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV60453894; called by muse, mutect2, varscan2
- PSG9 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs568316162, COSV52483483, COSV99392107; called by muse, varscan2
- PSMC5 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV56741216; called by muse, mutect2, varscan2
- PTDSS1 | c.973C>A p.L325I | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.401); catalogued as COSV61263791, COSV61265998; called by muse, mutect2
- PYROXD2 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV65329028; called by muse, mutect2, varscan2
- QARS1 | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.022); catalogued as COSV60274196; called by muse, mutect2, varscan2
- QSER1 | c.3067A>T p.S1023C (on ENST00000399302; = p.S1152C on NM_001076786.3) | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV67899710; called by muse, mutect2
- RAG1 | c.1801T>C p.S601P | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs145951370, CM1313155, COSV55024106; called by muse, mutect2, varscan2
- RALGAPA2 | c.3826C>T p.L1276F | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV52490239; called by muse, mutect2, varscan2
- RALGAPB | c.2681G>T p.R894M | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99484688; called by muse, mutect2, varscan2
- RALGAPB | c.2682G>T p.R894S | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99484689; called by muse, mutect2, varscan2
- RBBP6 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as rs748181118, COSV60503670; called by muse, mutect2, varscan2
- RGS18 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as rs770790858, COSV66507325; called by muse, mutect2, varscan2
- RGS7 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58532489; called by muse, mutect2, varscan2
- RND2 | c.638A>T p.E213V | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV56816310; called by muse, mutect2, varscan2
- RNF41 | c.688A>C p.K230Q | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV61504115; called by muse, mutect2, varscan2
- ROS1 | c.5248+1G>T p.X1750_splice | Splice Site (SNP) | VAF 19/27 reads (70%) | catalogued as rs573549832, COSV63852010, COSV63863171; called by muse, mutect2, varscan2
- RPS3 | c.66T>A p.N22K | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as COSV53704226; called by muse, mutect2, varscan2
- RPS6KA4 | c.2126T>C p.F709S | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53701047; called by muse, mutect2, varscan2
- RTL10 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1376094681, COSV60735435; called by muse, mutect2, varscan2
- RTN2 | c.980C>A p.P327Q | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.012); catalogued as COSV55592825; called by muse, mutect2, varscan2
- RTN3 | c.2096G>T p.G699V (on ENST00000377819 / NM_001265589.2; = p.G680V on NM_201428.3) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV58027241; called by muse, mutect2, varscan2
- RYR2 | c.9524T>A p.L3175Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV63667308; called by muse, mutect2, varscan2
- RYR2 | c.12017C>G p.S4006C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63667318; called by muse, mutect2, varscan2
- RYR3 | c.4958C>A p.P1653H | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101212240, COSV66780140, COSV66806728; called by muse, mutect2, varscan2
- SAMD12 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 94/148 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.207); catalogued as COSV59046705; called by muse, mutect2, varscan2
- SAR1B | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.074); catalogued as COSV68391330; called by muse, mutect2, varscan2
- SASH1 | c.2521G>T p.D841Y | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV66559338; called by muse, mutect2, varscan2
- SBF2 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 95/221 reads (43%) | catalogued as COSV56292975; called by muse, mutect2, varscan2
- SBSN | c.1653C>A p.S551R (on ENST00000452271 / NM_001166034.2; = p.S208R on NM_198538.4) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV101510030, COSV71733067; called by muse, mutect2, varscan2
- SCN10A | c.3911C>A p.A1304E | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV71860488; called by muse, mutect2, varscan2
- SCN4A | c.5132C>A p.S1711Y | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV71125804; called by muse, mutect2, varscan2
- SCYL2 | c.2348G>A p.G783E | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV62567837; called by muse, mutect2, varscan2
- SDK2 | c.4699C>T p.L1567F | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV66182246; called by muse, mutect2, varscan2
- SEMA4D | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV59391553; called by muse, mutect2, varscan2
- SERTAD2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as rs200657866, COSV57639742; called by muse, mutect2, varscan2
- SETBP1 | c.1593G>T p.R531S | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56314630; called by muse, mutect2, varscan2
- SETMAR | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62780433; called by muse, mutect2, varscan2
- SEZ6L | c.577G>T p.V193F | Missense Mutation (SNP) | VAF 105/152 reads (69%) | SIFT tolerated (0.49); PolyPhen benign (0.188); catalogued as COSV50658832; called by muse, mutect2, varscan2
- SFI1 | c.2030G>C p.S677T (on ENST00000400288 / NM_001007467.3; = p.S646T on NM_014775.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.291); catalogued as COSV66289900, COSV66291901; called by muse, mutect2, varscan2
- SH3BP2 | c.1574A>T p.E525V | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.325); catalogued as COSV62553646; called by muse, mutect2, varscan2
- SH3D21 | c.1218G>T p.K406N (on ENST00000453908 / NM_001162530.2; = p.K295N on NM_024676.5) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV54633624; called by muse, mutect2, varscan2
- SH3PXD2B | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV61125169; called by muse, mutect2, varscan2
- SH3RF2 | c.810C>G p.N270K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV63037553; called by muse, mutect2
- SHC3 | c.1606A>G p.M536V | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV65437038; called by muse, mutect2, varscan2
- SI | c.3630T>A p.H1210Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); catalogued as COSV52268387; called by muse, mutect2
- SIGLEC1 | c.943G>T p.V315F | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV52459574; called by muse, mutect2
- SIM1 | c.2214C>A p.H738Q | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV53489475; called by muse, mutect2, varscan2
- SLC12A1 | c.205T>A p.C69S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57708461; called by muse, mutect2, varscan2
- SLC12A5 | c.547C>A p.P183T (on ENST00000454036 / NM_001134771.2; = p.P160T on NM_020708.5) | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54789561; called by muse, mutect2
- SLC12A5 | c.1734C>G p.D578E (on ENST00000454036 / NM_001134771.2; = p.D555E on NM_020708.5) | Missense Mutation (SNP) | VAF 69/351 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV54789584, COSV54800424; called by muse, mutect2, varscan2
- SLC17A6 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54133992, COSV54134887; called by muse, mutect2, varscan2
- SLC1A3 | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 157/268 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.883); catalogued as COSV54314567; called by muse, mutect2, varscan2
- SLC1A6 | c.1650G>T p.E550D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.109); catalogued as COSV55668464; called by muse, mutect2, varscan2
- SLC35B3 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | catalogued as COSV59467451; called by muse, mutect2, varscan2
- SLC3A1 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200001778, CM014093, COSV53221277; called by muse, mutect2, varscan2
- SLC44A3 | c.1848A>C p.Q616H (on ENST00000271227 / NM_001114106.3; = p.Q568H on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99597776; called by muse, mutect2, varscan2
- SLC6A2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as rs147833183; called by muse, mutect2, varscan2
- SLC6A5 | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54224325; called by muse, mutect2, varscan2
- SLC6A7 | c.1271C>A p.A424E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV100045945, COSV100046466; called by muse, mutect2, varscan2
- SLCO2B1 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV56933399; called by muse, mutect2, varscan2
- SLCO6A1 | c.983C>A p.T328K | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV65806286; called by muse, mutect2
- SLFN13 | c.1342G>T p.D448Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759918653, COSV53192445; called by muse, mutect2, varscan2
- SLITRK2 | c.1820G>T p.S607I | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as COSV100157538, COSV59423527; called by muse, mutect2, varscan2
- SOX30 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs145755542; called by muse, mutect2, varscan2
- SPAG6 | c.875C>G p.A292G | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV57618328, COSV57618340; called by muse, mutect2, varscan2
- SPEG | c.6403G>T p.E2135* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | catalogued as COSV56664408; called by muse, mutect2
- SPON1 | c.2147G>T p.R716L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV59958132; called by muse, mutect2, varscan2
- SPTBN5 | c.8038G>T p.E2680* | Nonsense Mutation (SNP) | VAF 14/21 reads (67%) | catalogued as COSV58017368; called by muse, mutect2, varscan2
- SRPRA | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1327560875, COSV55005450; called by muse, varscan2
- SRSF6 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV54827120; called by muse, mutect2
- ST18 | c.986G>T p.R329M | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs983036670, COSV52486346; called by muse, mutect2, varscan2
- STAB2 | c.5404G>T p.D1802Y | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV66335332; called by muse, mutect2, varscan2
- STAT3 | c.1280A>G p.D427G | Missense Mutation (SNP) | VAF 71/586 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs749583802, COSV52884590; called by muse, mutect2, varscan2
- STXBP4 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 379/709 reads (53%) | catalogued as COSV54840457; called by muse, mutect2, varscan2
- SUGCT | c.251G>T p.W84L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV99999838; called by muse, mutect2, varscan2
- SUPT16H | c.3007G>C p.E1003Q | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as COSV52846151; called by muse, mutect2
- SURF2 | c.408G>C p.E136D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.637); catalogued as rs587634466, COSV64332143; called by muse, mutect2, varscan2
- SVEP1 | c.41T>A p.L14H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57030638; called by muse, varscan2
- SYCP2 | c.3723T>A p.Y1241* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV62766439; called by muse, mutect2, varscan2
- SYNPR | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV55723084; called by muse, mutect2, varscan2
- TAF1L | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 45/150 reads (30%) | catalogued as COSV54258805; called by muse, mutect2, varscan2
- TAS2R19 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 111/181 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV66828065; called by muse, mutect2, varscan2
- TBC1D12 | c.1835C>A p.A612D | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56552733; called by muse, mutect2, varscan2
- TCERG1L | c.511G>C p.A171P | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100894593, COSV64047352; called by muse, mutect2, varscan2
- TCTEX1D2 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV57487858; called by muse, mutect2, varscan2
- TDRD1 | c.1971G>C p.E657D | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV52588051; called by muse, mutect2, varscan2
- TEC | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV99972148; called by muse, mutect2
- TET1 | c.6345C>G p.D2115E | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65382517; called by muse, mutect2, varscan2
- TG | c.622G>T p.V208F | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV55067090; called by muse, mutect2, varscan2
- TGM4 | c.1681A>T p.I561F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as COSV56092996; called by mutect2, varscan2
- TH | c.187C>A p.P63T (on ENST00000381178 / NM_199292.3; = p.P32T on NM_000360.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV60766818, COSV60767395; called by muse, mutect2
- THAP6 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 82/155 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs774856709, COSV61161873; called by muse, mutect2, varscan2
- THBS2 | c.2095G>T p.G699C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64677340; called by muse, mutect2, varscan2
- THEMIS | c.1271C>A p.A424E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.532); catalogued as COSV64069555; called by muse, mutect2, varscan2
- THEMIS | c.712C>A p.R238= | Splice Region (SNP) | VAF 8/41 reads (20%) | catalogued as COSV64069556, COSV64070385; called by muse, mutect2, varscan2
- TIAM1 | c.1664A>G p.H555R | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.984); catalogued as rs1569063400, COSV54540137; called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.939A>T p.L313F | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV56694787; called by muse, mutect2, varscan2
- TMEM135 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV59697048; called by muse, mutect2, varscan2
- TMEM150C | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV71388759; called by muse, mutect2, varscan2
- TMEM171 | c.314A>C p.E105A | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as COSV55129574; called by muse, mutect2
- TMEM202 | c.362T>A p.F121Y | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV58981953; called by muse, mutect2, varscan2
- TMEM266 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 67/91 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66378741; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1429G>T p.V477L | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV54868604; called by muse, mutect2, varscan2
- TRPC4 | c.2133G>T p.R711S (on ENST00000379705 / NM_016179.4; = p.R716S on NM_003306.3) | Missense Mutation (SNP) | VAF 110/167 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV58992192, COSV59011779; called by muse, mutect2, varscan2
- TRPV4 | c.2276G>T p.G759V | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55680659; called by muse, mutect2, varscan2
- TTC21B | c.2512G>T p.A838S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as COSV54628304, COSV54632025; called by muse, mutect2, varscan2
- TTN | c.99237G>C p.E33079D (on ENST00000591111; = p.E25655D on NM_003319.4) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | PolyPhen benign (0.003); catalogued as COSV59915214; called by muse, mutect2, varscan2
- TUB | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV59488332, COSV59490177; called by muse, mutect2, varscan2
- TUBA3C | c.1186G>C p.D396H | Missense Mutation (SNP) | VAF 95/167 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as rs994945064, COSV68027701, COSV68028619; called by muse, mutect2, varscan2
- TUBB4A | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 72/113 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.335); catalogued as COSV51152418; called by muse, mutect2, varscan2
- TUT4 | c.3993A>T p.E1331D | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.139); catalogued as COSV57110716; called by muse, mutect2, varscan2
- TXLNB | c.1897C>A p.P633T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV64443263; called by muse, mutect2, varscan2
- TXLNB | c.1520T>G p.F507C | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV64443268; called by muse, mutect2, varscan2
- TXNDC16 | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV99908771; called by muse, mutect2, varscan2
- TXNDC16 | c.1974G>T p.L658F | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.338); catalogued as COSV99908775; called by muse, mutect2, varscan2
- UBE3A | c.1095T>A p.D365E | Missense Mutation (SNP) | VAF 103/151 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.109); catalogued as rs375600705, COSV51661856; called by muse, mutect2, varscan2
- UCMA | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.168); catalogued as COSV66321319; called by muse, mutect2, varscan2
- UGT1A5 | c.519G>T p.L173F | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as COSV59383635; called by muse, mutect2, varscan2
- UGT2B28 | c.1089A>G p.L363= | Splice Region (SNP) | VAF 27/81 reads (33%) | catalogued as COSV59430910; called by muse, mutect2, varscan2
- UGT8 | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60416519, COSV60416640; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3001G>T p.D1001Y | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV54435018; called by muse, mutect2, varscan2
- UNC5C | c.382C>G p.R128G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV71658457; called by muse, mutect2, varscan2
- UNC79 | c.4853C>A p.P1618H (on ENST00000393151 / NM_001346218.2; = p.P1441H on NM_020818.5) | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV56376690; called by muse, mutect2, varscan2
- UNC79 | c.5266C>A p.L1756I (on ENST00000393151 / NM_001346218.2; = p.L1579I on NM_020818.5) | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV56376703; called by muse, mutect2, varscan2
- USP10 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.054); catalogued as COSV54747428; called by muse, mutect2, varscan2
- USP8 | c.1747A>T p.K583* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV56162762; called by muse, mutect2, varscan2
- VANGL1 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.452); catalogued as COSV100048825; called by muse, mutect2, varscan2
- VCAN | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV54098560, COSV54100011; called by muse, mutect2, varscan2
- WAPL | c.2482+1G>C p.X828_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as COSV53932802; called by muse, mutect2, varscan2
- WARS2 | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1219375586, COSV52476233; called by muse, mutect2, varscan2
- XIRP2 | c.6575C>T p.P2192L (on ENST00000628543; = p.P2367L on NM_152381.6) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.028); catalogued as rs748946006, COSV54685874; called by muse, mutect2, varscan2
- YPEL2 | c.153T>G p.F51L | Missense Mutation (SNP) | VAF 94/320 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57070836; called by muse, mutect2, varscan2
- ZACN | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.044); catalogued as rs1187341850, COSV58035190; called by muse, mutect2, varscan2
- ZAN | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61805874; called by muse, mutect2, varscan2
- ZBTB10 | c.1514G>T p.R505L | Missense Mutation (SNP) | VAF 133/194 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV66946559; called by muse, mutect2, varscan2
- ZBTB14 | c.709C>G p.Q237E | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV63696287; called by muse, mutect2, varscan2
- ZFC3H1 | c.2452A>T p.R818W | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV66430610; called by muse, mutect2, varscan2
- ZFHX4 | c.2947A>T p.S983C | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs1440098799, COSV50551885; called by muse, mutect2, varscan2
- ZFYVE1 | c.2279G>T p.W760L | Missense Mutation (SNP) | VAF 57/81 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59610015; called by muse, mutect2, varscan2
- ZIK1 | c.625A>T p.S209C | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as rs1435129570, COSV56736537, COSV56737816; called by muse, mutect2, varscan2
- ZNF107 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs550495438, COSV61327156; called by muse, mutect2, varscan2
- ZNF148 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as COSV62302593; called by muse, mutect2, varscan2
- ZNF267 | c.890A>T p.Y297F | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56250952; called by muse, mutect2, varscan2
- ZNF282 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50479179; called by muse, mutect2, varscan2
- ZNF354C | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV59607421; called by muse, mutect2, varscan2
- ZNF385D | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV55747958; called by muse, mutect2, varscan2
- ZNF398 | c.1168C>T p.Q390* (on ENST00000475153 / NM_170686.3; = p.Q219* on NM_020781.4) | Nonsense Mutation (SNP) | VAF 111/283 reads (39%) | catalogued as COSV60064670, COSV60065064; called by muse, mutect2, varscan2
- ZNF461 | c.181G>C p.G61R | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV64453036; called by muse, mutect2, varscan2
- ZNF536 | c.1472G>T p.C491F | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.87); catalogued as rs771944197, COSV62819746; called by muse, mutect2, varscan2
- ZNF536 | c.2420A>G p.N807S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100834625; called by muse, mutect2, varscan2
- ZNF555 | c.1079G>C p.R360T | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV100514513; called by muse, mutect2, varscan2
- ZNF555 | c.1080G>T p.R360S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100514518; called by muse, mutect2, varscan2
- ZNF676 | c.872G>T p.G291V (on ENST00000650058; = p.G259V on NM_001001411.3) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV68092365; called by muse, varscan2
- ZNF746 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV61406558; called by muse, varscan2
- ZNF831 | c.170C>A p.A57D | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64037988; called by muse, mutect2, varscan2
- ABCA13 | c.5652del p.V1886Wfs*4 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- ACACA | c.5233del p.A1745Qfs*32 | Frame Shift Del (DEL) | VAF 66/146 reads (45%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.1808A>T p.Y603F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- AP1G1 | c.1738del p.L580Yfs*11 | Frame Shift Del (DEL) | VAF 36/161 reads (22%) | called by mutect2, pindel, varscan2
- C16orf82 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CCDC27 | c.1241A>T p.Q414L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2
- CD37 | c.445del p.Q149Sfs*19 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | called by mutect2, pindel, varscan2
- F7 | c.972dup p.E325Rfs*6 | Frame Shift Ins (INS) | VAF 35/74 reads (47%) | called by mutect2, pindel, varscan2
- GDF10 | c.619T>A p.S207T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- GIMAP1 | c.548dup p.R184Pfs*6 | Frame Shift Ins (INS) | VAF 38/94 reads (40%) | called by mutect2, pindel, varscan2
- GOLGA2 | c.842_845del p.R281Tfs*17 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | called by mutect2, pindel, varscan2
- KRTAP19-6 | c.171_174delinsTAA p.Y58Nfs*28 | Frame Shift Del (DEL) | VAF 72/140 reads (51%) | called by mutect2*, pindel, varscan2*
- LZTR1 | c.352del p.R118Vfs*29 | Frame Shift Del (DEL) | VAF 35/72 reads (49%) | called by mutect2, pindel, varscan2
- MRPL45 | c.837G>T p.T279= | Splice Region (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- NAT2 | c.399dup p.P134Afs*44 | Frame Shift Ins (INS) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- OR56A4 | c.1055dup p.E353Gfs*29 | Frame Shift Ins (INS) | VAF 30/86 reads (35%) | called by mutect2, pindel, varscan2
- PSKH2 | c.1156dup p.*386Lfs*4 | Frame Shift Ins (INS) | VAF 79/148 reads (53%) | called by mutect2, pindel, varscan2
- SALL1 | c.2185_2186del p.T729Wfs*6 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | called by pindel, varscan2
- SCNN1D | c.1261_1271del p.C421Pfs*60 (on ENST00000338555; = p.C585Pfs*60 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 13/123 reads (11%) | called by mutect2, pindel
- SELENOV | c.853_854del p.S285Pfs*? | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | called by pindel, varscan2
- SLC4A1 | c.2353del p.L785Wfs*44 | Frame Shift Del (DEL) | VAF 54/131 reads (41%) | called by mutect2, pindel, varscan2
- SOWAHB | c.2183dup p.K729Qfs*26 | Frame Shift Ins (INS) | VAF 120/309 reads (39%) | called by mutect2, pindel, varscan2
- TRAV22 | c.195C>G p.N65K | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- UGT2A1 | c.635_640del p.N212_F213del | In Frame Del (DEL) | VAF 45/85 reads (53%) | called by mutect2, pindel, varscan2
- WDR17 | c.694del p.D232Tfs*9 | Frame Shift Del (DEL) | VAF 21/161 reads (13%) | called by mutect2, pindel, varscan2
- ABCA4 | c.5607G>C p.P1869= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV64671529; called by muse, mutect2, varscan2
- AC092143.1 | c.1977G>T p.T659= | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as COSV59247210; called by muse, mutect2, varscan2
- ADAMTS12 | c.3666C>A p.P1222= | Silent (SNP) | VAF 49/92 reads (53%) | catalogued as COSV61256861, COSV61274230; called by muse, mutect2, varscan2
- ANK2 | c.7122C>A p.A2374= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV52148965; called by muse, mutect2, varscan2
- AP3M2 | c.1068G>T p.G356= | Silent (SNP) | VAF 60/212 reads (28%) | catalogued as COSV51527830; called by muse, mutect2, varscan2
- APOB | c.5283C>A p.G1761= | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as COSV51925743, COSV99268639; called by muse, mutect2, varscan2
- ASXL3 | c.3528G>T p.R1176= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV52459116; called by muse, mutect2, varscan2
- BACH2 | c.2379G>T p.G793= | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as COSV57585805; called by muse, mutect2, varscan2
- C1QC | c.66G>C p.L22= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV65889313; called by muse, mutect2, varscan2
- CATSPERB | c.2364A>T p.V788= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV56422905; called by muse, mutect2, varscan2
- CCDC88B | c.3924C>A p.P1308= | Silent (SNP) | VAF 53/219 reads (24%) | catalogued as COSV57265150; called by muse, mutect2, varscan2
- CD200R1L | c.183T>C p.N61= | Silent (SNP) | VAF 43/88 reads (49%) | catalogued as rs1224751336, COSV68003878; called by muse, mutect2, varscan2
- CDH2 | c.981T>G p.T327= | Silent (SNP) | VAF 89/219 reads (41%) | catalogued as COSV52273234; called by muse, mutect2, varscan2
- CHD4 | c.2296C>T p.L766= (on ENST00000357008 / NM_001363606.2; = p.L779= on NM_001273.5) | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs530395831, COSV58895989; called by muse, mutect2, varscan2
- CLIP3 | c.351C>T p.T117= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs749887537, COSV62111840; called by muse, mutect2, varscan2
- CNBD2 | c.631C>T p.L211= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as COSV62586463; called by muse, mutect2, varscan2
- COL22A1 | c.18G>T p.G6= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as COSV57326547; called by muse, varscan2
- COL2A1 | c.1923A>C p.A641= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as COSV61528417; called by muse, mutect2, varscan2
- CRB2 | c.252C>A p.P84= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV63501996; called by muse, mutect2, varscan2
- CSMD1 | c.1089C>T p.S363= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs576618220, COSV68174188; called by muse, mutect2, varscan2
- CTAGE1 | c.30T>C p.F10= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV66943011; called by muse, mutect2, varscan2
- CUBN | c.4830A>G p.R1610= | Silent (SNP) | VAF 120/197 reads (61%) | catalogued as COSV64709191; called by muse, mutect2, varscan2
- CUL7 | c.816G>A p.A272= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs772341987, COSV54813753; called by mutect2, varscan2
- CXCR5 | c.558C>A p.L186= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV52682477; called by muse, mutect2, varscan2
- CYP4F11 | c.240G>T p.L80= | Silent (SNP) | VAF 98/158 reads (62%) | catalogued as COSV56125879; called by muse, mutect2, varscan2
- DDO | c.540C>A p.V180= (on ENST00000368924 / NM_001368172.1; = p.V121= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 81/159 reads (51%) | catalogued as COSV64469766; called by muse, mutect2, varscan2
- DHPS | c.721C>T p.L241= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV52951640; called by muse, mutect2, varscan2
- DMP1 | c.1359C>T p.D453= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV56818852; called by muse, mutect2, varscan2
- DPP6 | c.927T>C p.D309= (on ENST00000377770 / NM_001364500.2; = p.D247= on NM_001936.5) | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as COSV59600786; called by muse, mutect2, varscan2
- DSC3 | c.1749C>G p.V583= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV64571957, COSV64574951; called by muse, mutect2, varscan2
- ERN1 | c.1923C>T p.A641= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV70500686; called by muse, mutect2, varscan2
- FAHD2B | c.201G>T p.T67= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV55630056, COSV55630507; called by muse, mutect2, varscan2
- FARP2 | c.504G>A p.L168= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV50869437; called by muse, mutect2, varscan2
- FGA | c.1392C>A p.T464= | Silent (SNP) | VAF 54/133 reads (41%) | catalogued as rs779394316, COSV100119984; called by muse, mutect2, varscan2
- FHL5 | c.108A>T p.V36= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as COSV58735627, COSV58739291; called by muse, mutect2, varscan2
- FLG | c.1803A>T p.S601= | Silent (SNP) | VAF 65/352 reads (18%) | catalogued as COSV64237814; called by muse, mutect2, varscan2
- FREM1 | c.4506G>T p.V1502= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV66518779; called by muse, mutect2, varscan2
- GAB2 | c.903C>A p.T301= (on ENST00000361507 / NM_080491.3; = p.T263= on NM_012296.3) | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV60866371; called by muse, mutect2, varscan2
- GABRA2 | c.429T>C p.N143= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV62912525; called by muse, varscan2
- GNL2 | c.708C>T p.H236= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV66079694; called by muse, mutect2, varscan2
- GPR158 | c.3627C>A p.I1209= | Silent (SNP) | VAF 48/68 reads (71%) | catalogued as rs200332195, COSV66266324; called by muse, mutect2, varscan2
- H2AC20 | c.309C>A p.I103= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV58611368, COSV58611552; called by muse, mutect2, varscan2
- HAUS3 | c.519T>G p.V173= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV54721963; called by muse, mutect2, varscan2
- IGHA2 | c.219G>A p.P73= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs781958889; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.279A>C p.T93= | Silent (SNP) | VAF 107/561 reads (19%) | called by muse, mutect2, varscan2
- IGSF21 | c.165G>T p.R55= | Silent (SNP) | VAF 49/70 reads (70%) | catalogued as COSV52124475, COSV52126703; called by muse, mutect2, varscan2
- IL18R1 | c.618A>T p.I206= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV52122930; called by muse, mutect2, varscan2
- IL7R | c.510C>A p.R170= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV57406435; called by muse, mutect2
- ITGA3 | c.1623C>T p.G541= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV99143230; called by muse, mutect2, varscan2
- ITGA8 | c.2586G>T p.L862= | Silent (SNP) | VAF 55/77 reads (71%) | catalogued as COSV65225565; called by muse, mutect2, varscan2
- ITPKB | c.120A>T p.A40= | Silent (SNP) | VAF 5/8 reads (63%) | called by mutect2, varscan2
- KDM2B | c.1122G>T p.V374= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV65638577; called by muse, mutect2, varscan2
- KERA | c.300A>T p.I100= | Silent (SNP) | VAF 55/89 reads (62%) | catalogued as COSV99899293; called by muse, varscan2
- KIF2B | c.903C>A p.A301= | Silent (SNP) | VAF 58/98 reads (59%) | catalogued as COSV52127621; called by muse, mutect2, varscan2
- LILRB1 | c.1383C>A p.G461= (on ENST00000427581; = p.G425= on NM_006669.6) | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV61116209, COSV61116409; called by muse, mutect2, varscan2
- LILRB5 | c.801T>A p.S267= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as COSV60255149; called by muse, mutect2, varscan2
- LIPN | c.1153C>A p.R385= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV101356206, COSV101356225; called by muse, mutect2
- LTBP1 | c.2931G>T p.G977= (on ENST00000404816 / NM_206943.4; = p.G651= on NM_000627.4) | Silent (SNP) | VAF 99/170 reads (58%) | catalogued as COSV63181392; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.225G>A p.L75= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV58186265; called by muse, mutect2, varscan2
- LYPD3 | c.573G>T p.R191= | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV54987918; called by muse, mutect2, varscan2
- MAP1B | c.849C>A p.L283= | Silent (SNP) | VAF 61/94 reads (65%) | catalogued as COSV57094823; called by muse, mutect2, varscan2
- MARCHF7 | c.510A>T p.S170= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV52027811; called by muse, mutect2, varscan2
- MDN1 | c.3714G>A p.L1238= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV65518193; called by muse, mutect2, varscan2
- MLLT6 | c.1902C>T p.A634= | Silent (SNP) | VAF 31/201 reads (15%) | catalogued as rs200175117; called by muse, mutect2, varscan2
- MRPL11 | c.51C>T p.G17= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as rs1169254696, COSV60598453; called by muse, varscan2
- MUC17 | c.7422C>A p.G2474= | Silent (SNP) | VAF 278/433 reads (64%) | catalogued as COSV60281742; called by muse, mutect2, varscan2
- MUC5AC | c.834C>T p.C278= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs539241490, COSV62253427; called by muse, mutect2, varscan2
- MUC5AC | c.1527G>A p.V509= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1224736952, COSV62253439, COSV62255043; called by muse, mutect2, varscan2
- MUC5B | c.6030C>T p.P2010= | Silent (SNP) | VAF 46/538 reads (9%) | catalogued as rs772035496, COSV101500589, COSV71590403; called by muse, mutect2
- MUSK | c.723C>A p.P241= | Silent (SNP) | VAF 65/147 reads (44%) | catalogued as rs1220706703, COSV51879370; called by muse, mutect2, varscan2
- MYH1 | c.4083A>G p.L1361= | Silent (SNP) | VAF 108/146 reads (74%) | catalogued as COSV56844570; called by muse, mutect2, varscan2
- NANOS3 | c.474C>T p.A158= (on ENST00000397555; = p.A177= on NM_001098622.2) | Silent (SNP) | VAF 40/63 reads (63%) | catalogued as rs770731914, COSV59248481; called by muse, mutect2, varscan2
- NCAM1 | c.1341A>T p.S447= (on ENST00000316851 / NM_181351.5; = p.S437= on NM_000615.7) | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as COSV57511630; called by muse, mutect2, varscan2
- NETO1 | c.1050C>T p.S350= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs1412378710, COSV100199073, COSV55002501; called by muse, mutect2, varscan2
- NFATC1 | c.2022C>T p.V674= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV53696127; called by muse, mutect2, varscan2
- NINL | c.948C>T p.D316= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs377706873; called by muse, mutect2, varscan2
- NOS1AP | c.511C>T p.L171= | Silent (SNP) | VAF 62/132 reads (47%) | catalogued as COSV62632561; called by muse, mutect2, varscan2
- NOS2 | c.762G>A p.K254= | Silent (SNP) | VAF 27/226 reads (12%) | catalogued as COSV58222233; called by muse, mutect2, varscan2
- NRCAM | c.2856C>T p.P952= (on ENST00000379028 / NM_001371124.1; = p.P936= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 46/55 reads (84%) | catalogued as rs775597024, COSV100694773, COSV61032027; called by muse, mutect2, varscan2
- NRXN3 | c.1803C>T p.N601= (on ENST00000557594 / NM_001272020.2; = p.N1025= on NM_004796.6) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV55317628; called by muse, mutect2, varscan2
- OR10H1 | c.253C>T p.L85= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100612356; called by muse, mutect2, varscan2
- OR10Z1 | c.318A>G p.S106= | Silent (SNP) | VAF 69/222 reads (31%) | catalogued as rs908729354, COSV63524008; called by muse, mutect2, varscan2
- OR1J2 | c.96G>T p.L32= | Silent (SNP) | VAF 103/256 reads (40%) | catalogued as COSV58943879; called by muse, mutect2, varscan2
- OR1J4 | c.855G>C p.L285= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV61589606; called by muse, mutect2, varscan2
- OR2B3 | c.864C>T p.L288= | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as COSV65850775; called by muse, mutect2, varscan2
- OR2M4 | c.45G>T p.L15= | Silent (SNP) | VAF 55/145 reads (38%) | catalogued as rs1325590349, COSV100140968; called by muse, mutect2, varscan2
- OR2M5 | c.429T>A p.L143= | Silent (SNP) | VAF 45/347 reads (13%) | catalogued as COSV63545835; called by muse, mutect2, varscan2
- OR4N2 | c.258C>A p.L86= | Silent (SNP) | VAF 88/250 reads (35%) | catalogued as COSV60050251; called by muse, varscan2
- OR56A1 | c.381G>A p.V127= | Silent (SNP) | VAF 66/121 reads (55%) | catalogued as COSV100360390; called by muse, mutect2, varscan2
- OVCH1 | c.696C>G p.A232= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV100548177, COSV58959972; called by muse, mutect2, varscan2
- PCDHB12 | c.618G>T p.P206= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV53393750, COSV53398507; called by muse, mutect2, varscan2
- PCDHB2 | c.2091C>A p.A697= | Silent (SNP) | VAF 77/206 reads (37%) | catalogued as COSV50564832; called by muse, varscan2
- PCDHB7 | c.411G>A p.E137= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV50755839; called by muse, mutect2, varscan2
- PCK1 | c.1242C>T p.P414= | Silent (SNP) | VAF 113/315 reads (36%) | catalogued as COSV60126505; called by muse, mutect2, varscan2
- PCLO | c.13956A>T p.S4652= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as COSV61619492; called by muse, mutect2, varscan2
- PHF21B | c.501C>T p.T167= | Silent (SNP) | VAF 33/43 reads (77%) | catalogued as rs765319355, COSV57556402; called by muse, mutect2, varscan2
- PIK3CG | c.2697G>A p.T899= | Silent (SNP) | VAF 110/140 reads (79%) | catalogued as rs1180238527, COSV63246127; called by muse, mutect2, varscan2
- PIWIL1 | c.1743C>A p.T581= | Silent (SNP) | VAF 61/84 reads (73%) | catalogued as COSV55344708; called by muse, mutect2, varscan2
- PLXDC2 | c.954G>T p.S318= | Silent (SNP) | VAF 92/139 reads (66%) | catalogued as COSV65901388; called by muse, mutect2, varscan2
- PNPLA7 | c.2802A>C p.G934= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99480020; called by muse, mutect2
- POU4F3 | c.345C>T p.L115= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV57942595; called by muse, mutect2, varscan2
- PRDM12 | c.630G>T p.L210= | Silent (SNP) | VAF 52/167 reads (31%) | catalogued as COSV53389874; called by muse, mutect2
- PRKCG | c.21C>G p.G7= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs779036291, COSV54724687; called by muse, mutect2, varscan2
- PSMB7 | c.432G>T p.G144= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV52329486; called by muse, mutect2, varscan2
- PSMC5 | c.213C>A p.S71= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV99856196; called by muse, mutect2, varscan2
- PTPRD | c.5610A>T p.V1870= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV61931803; called by muse, mutect2, varscan2
- PTPRT | c.1375C>A p.R459= | Silent (SNP) | VAF 70/116 reads (60%) | catalogued as COSV100625082, COSV62003232; called by muse, mutect2, varscan2
- RHOXF2 | c.249C>A p.A83= | Silent (SNP) | VAF 39/50 reads (78%) | catalogued as COSV65047706; called by muse, mutect2, varscan2
- RIC3 | c.285G>T p.L95= | Silent (SNP) | VAF 56/171 reads (33%) | catalogued as COSV58300725; called by muse, mutect2, varscan2
- RIN3 | c.705G>T p.V235= | Silent (SNP) | VAF 58/173 reads (34%) | catalogued as COSV53645746; called by muse, mutect2, varscan2
- RNF17 | c.3375C>T p.P1125= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV55035242; called by muse, mutect2, varscan2
- ROBO2 | c.3048T>G p.P1016= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV59899905; called by muse, mutect2, varscan2
- RTTN | c.4707A>T p.T1569= | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as rs143709749; called by muse, mutect2, varscan2
- SACS | c.4557A>G p.G1519= | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as COSV66535634; called by muse, mutect2, varscan2
- SEMA3C | c.1167C>T p.T389= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as COSV54842215; called by muse, mutect2, varscan2
- SLC5A12 | c.864G>T p.V288= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV54819446, COSV54822873; called by muse, mutect2, varscan2
- SLC6A2 | c.1035G>T p.L345= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as COSV54913989, COSV54921574; called by muse, mutect2, varscan2
- SNAP25 | c.168A>G p.Q56= | Silent (SNP) | VAF 36/202 reads (18%) | catalogued as COSV54770863; called by muse, mutect2, varscan2
- SP4 | c.744T>C p.G248= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV56021070; called by muse, mutect2, varscan2
- SPG11 | c.2499C>T p.F833= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as COSV55991622; called by muse, mutect2, varscan2
- SPICE1 | c.411T>G p.P137= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV55618645; called by muse, mutect2, varscan2
- STK38L | c.1323T>C p.Y441= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as rs763883106, COSV66520709; called by muse, mutect2, varscan2
- STOX1 | c.1968T>C p.C656= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as COSV53813364; called by muse, mutect2, varscan2
- STX19 | c.96G>A p.G32= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV57396596; called by muse, mutect2, varscan2
- STYXL2 | c.2490T>C p.N830= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as rs1429147955, COSV54802614; called by muse, mutect2, varscan2
- TAF1 | c.5355G>A p.E1785= (on ENST00000373790 / NM_138923.4; = p.E1806= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV52108519; called by muse, mutect2, varscan2
- TCTEX1D2 | c.153G>T p.V51= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV57487871; called by muse, mutect2, varscan2
- TEAD2 | c.1086G>T p.R362= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV60543575; called by muse, mutect2, varscan2
- TKTL2 | c.72G>T p.R24= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99761075; called by muse, mutect2, varscan2
- TPP1 | c.1062G>T p.L354= | Silent (SNP) | VAF 38/166 reads (23%) | catalogued as CD120854, COSV54993589; called by muse, mutect2, varscan2
- TYMS | c.663C>T p.L221= | Silent (SNP) | VAF 34/270 reads (13%) | catalogued as rs757484292, COSV51890862; called by muse, mutect2, varscan2
- ULK1 | c.741C>G p.T247= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs892453657, COSV58855008; called by muse, mutect2, varscan2
- USP24 | c.4188A>G p.Q1396= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV53762967; called by muse, mutect2, varscan2
- VANGL1 | c.315G>T p.L105= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as COSV100048820; called by muse, mutect2, varscan2
- VN1R2 | c.861C>T p.V287= | Silent (SNP) | VAF 69/130 reads (53%) | catalogued as rs1219602697, COSV59037347, COSV59038816; called by muse, mutect2, varscan2
- VN1R2 | c.993C>A p.S331= | Silent (SNP) | VAF 39/172 reads (23%) | catalogued as COSV59037357, COSV59037417; called by muse, mutect2, varscan2
- XCR1 | c.624C>A p.I208= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV58569138; called by muse, mutect2, varscan2
- ZAN | c.2697C>A p.L899= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV61805887; called by muse, varscan2
- ZNF251 | c.1770G>T p.G590= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV52956498; called by muse, mutect2, varscan2
- ZNF257 | c.337T>C p.L113= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV71306324; called by muse, mutect2, varscan2
- ZNF521 | c.216G>T p.L72= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV64123200; called by muse, mutect2, varscan2
- ZNF609 | c.777G>T p.V259= | Silent (SNP) | VAF 145/214 reads (68%) | catalogued as COSV58580412; called by muse, mutect2, varscan2
- ZNF611 | c.1521G>A p.E507= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as rs780930363, COSV60539717; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851830 T>A | 3'Flank (SNP) | VAF 71/89 reads (80%) | called by muse, mutect2, varscan2
- AMFR | c.*263G>C | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99315605; called by muse, mutect2, varscan2
- BTN2A3P | n.1177G>T | RNA (SNP) | VAF 32/43 reads (74%) | called by muse, mutect2, varscan2
- CPLANE1 | chr5:37167127 T>G | 3'Flank (SNP) | VAF 10/66 reads (15%) | catalogued as COSV57054107; called by muse, mutect2, varscan2
- MIR1324 | n.57G>C | RNA (SNP) | VAF 8/65 reads (12%) | catalogued as rs1222477014; called by muse, mutect2, varscan2
- MIR206 | n.16C>T | RNA (SNP) | VAF 85/103 reads (83%) | catalogued as rs982492642; called by muse, mutect2, varscan2
- MORF4 | n.387C>T | RNA (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- PARGP1 | n.615G>T | RNA (SNP) | VAF 16/50 reads (32%) | catalogued as rs1423818751; called by muse, mutect2, varscan2
- PCDH15 | c.91+56249C>A | Intron (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100214929; called by muse, mutect2
- PKD1L2 | n.1325G>T | RNA (SNP) | VAF 104/226 reads (46%) | catalogued as rs1369054754; called by muse, mutect2, varscan2
- POLA1 | c.2947-21320G>A | Intron (SNP) | VAF 55/77 reads (71%) | called by muse, mutect2, varscan2
- SNORD115-34 | n.78G>A | RNA (SNP) | VAF 99/310 reads (32%) | catalogued as rs1046323311; called by muse, mutect2, varscan2
- SPATA8 | n.757C>T | RNA (SNP) | VAF 34/57 reads (60%) | catalogued as rs1232742624, COSV60704178; called by muse, mutect2, varscan2
- TTN | c.10360+3698G>A | Intron (SNP) | VAF 18/56 reads (32%) | catalogued as rs778632877, COSV59915231, COSV60241862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UVSSA | c.*9537G>C | 3'UTR (SNP) | VAF 255/558 reads (46%) | catalogued as COSV61347722; called by muse, mutect2, varscan2
